CCDI case PBBYTM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/4a7aabe1-8d8d-43c4-9767-d9f2ad2bd2a7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sclerosing stromal tumor: ICD-O-3 morphology code: 8602/0; Tissue or organ of origin: Ovary; Age at diagnosis: 15.3 years (5,584 days).

Biospecimens (3 samples)
- Sample 0DL0IU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL0J3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL0JW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
